Gene-level copy-number profile of tumor specimen TCGA-A3-3363-01A from TCGA case TCGA-A3-3363, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 50.9 years (18,596 days).
Specimen TCGA-A3-3363-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KIRC.c264da82-98d1-40f6-8988-6880fe03bbe9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A3-3363-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cb861d70-423c-43c8-afc5-067311dae47e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,421; copy number 2: 52,653; copy number 3: 4,013; copy number 4: 338; copy number 5: 265; copy number 6: 17; copy number 7: 113.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A3-3363-01A-01D-0858-01): tumor purity 0.79, ploidy 2.07, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 395 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:96,940,068–97,437,896, 11 genes, copy number 5: RN7SL252P, DLX6-AS1, AC004774.1, AC004774.3, DLX6, AC004774.2, DLX5, SDHAF3, HMGB3P21, AC073900.1, AP1S2P1.
- chr7:100,330,777–102,464,863, 97 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr7:115,207,894–116,954,334, 27 genes, copy number 5: Y_RNA, POLR2DP2, SNORA25B, AC092590.1, AC093714.1, AC093714.2, Y_RNA, TFEC, AC073130.3, TES, AC073130.2, AC002066.1, AC073130.1, CAV2, Metazoa_SRP, CAV1, AC006159.1, AC006159.2, COMETT, MET, CAPZA2, AC002543.1, Y_RNA, RNA5SP239, ST7-AS1, AC106873.5, AC106873.7.
- chr7:116,953,899–117,119,719, 9 genes, copy number 5 (within-gene range 4–5): ST7-OT4, AC106873.8, AC106873.3, AC106873.2, AC106873.6, AC106873.4, AC106873.1, TPM3P1, MIR6132.
- chr7:138,797,952–141,052,409, 51 genes, copy number 5 (within-gene range 3–5): TMEM213, KIAA1549, RNU6-1272P, ZC3HAV1L, ZC3HAV1, AC018644.1, TTC26, AC009220.2, AC009220.3, AC009220.1, MZT1P2, UBN2, RNU6-206P, FMC1, LUC7L2, FMC1-LUC7L2, AC083880.1, RNU6-911P, KLRG2, AC005531.1, CLEC2L, ERHP1, HIPK2, TBXAS1, PARP12, KDM7A, Y_RNA, KDM7A-DT, RNU6-797P, RNU1-58P, AC005377.1, PPP1R2P6, SLC37A3, RNA5SP247, RNA5SP248, RAB19, AC069335.1, MKRN1, DENND2A, Y_RNA, AC006452.1, RN7SL771P, ADCK2, NDUFB2, NDUFB2-AS1, BRAF, RNU6-85P, AC006006.1, CCT4P1, MRPS33, RNU4-74P.
- chr7:143,954,844–144,195,833, 17 genes, copy number 6: OR2F1, CAPZA1P5, OR2Q1P, SLC16A1P1, OR6B1, OR2A5, OR2A25, OR2A41P, OR2A12, OR2A2, OR2A15P, OR2A14, OR2A13P, OR2A3P, OR2AO1P, CTAGE4, ARHGEF35.
- chr7:148,543,677–152,676,141, 142 genes, copy number 5–7 (broad region; genes not listed).
- chr7:155,067,034–155,966,343, 27 genes, copy number 5–7: HTR5A-AS1, HTR5A, AC093726.3, AC092628.2, AC092628.1, RN7SKP280, AC099552.1, AC099552.3, AC099552.5, AC099552.4, AC099552.2, AC144652.1, INSIG1, BLACE, AC008060.1, AC008060.4, AC008060.5, AC008060.3, EN2, CNPY1, AC009403.2, AC008060.2, AC009403.3, AC009403.1, RBM33, SHH, AC021218.1.
- chr7:158,532,718–159,233,377, 14 genes, copy number 5: MIR595, AC078942.1, LINC01022, MIR5707, THAP5P1, NCAPG2, AC019084.1, ESYT2, DYNC2I1, AC004863.1, LINC00689, VIPR2, AC007269.1, PIP5K1P2.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
